Somatic mutation profile of tumor specimen 0DN1D4 from CCDI case PBCBBE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,019 days).
Specimen 0DN1D4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a499ca-43fd-4136-9f67-36f64c654c10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35cb6da2-d5f7-472f-ba35-7f53cfb0ce1d

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC5B | c.2678G>A p.G893D | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCNT | c.1644G>A p.A548= | Silent (SNP) | VAF 209/750 reads (28%) | catalogued as rs538874919; called by muse, mutect2, varscan2
- SORBS2 | c.684+7734G>A | Intron (SNP) | VAF 266/902 reads (29%) | catalogued as rs954237870, COSV52997162; called by muse, varscan2
